Gene-level copy-number profile of tumor specimen C3L-00904-01 from CPTAC case C3L-00904, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 71.7 years (26,190 days).
Specimen C3L-00904-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 62aac655-602a-40e2-9b52-5f107f0f7188.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00904-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/3d3a7a73-5484-492a-8434-62f605a73c47

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 18,564; copy number 2: 34,874; copy number 3: 5,379; copy number 4: 78; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,118,534–87,120,980, 1 gene: ANAPC1P3.
- chr5:108,784,098–108,830,790, 2 genes (within-gene range 0–1): AC034207.1, AC008871.1.
- chr5:165,349,030–165,783,134, 3 genes: AC008415.1, RN7SKP60, AC008562.1.
- chr16:32,262,827–32,460,362, 9 genes: AC133485.2, AC140878.1, AC133548.2, AC133548.1, ACTR3BP3, AC138915.2, PABPC1P13, AC138915.3, AC138915.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:32,103,245–32,188,107, 1 gene, copy number 5 (within-gene range 1–5): HERC2P4.
- chr16:32,126,432–32,132,724, 1 gene, copy number 5: AC133485.7.

Autosomal genes at a single copy (total copy number 1): 16,265. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
